Somatic mutation profile of tumor specimen 0DRKKM from CCDI case PBCGUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 12.0 years (4,396 days).
Specimen 0DRKKM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b366b95-2981-4692-8e26-1d2fec203520.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRKKY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4149a54a-dd3e-4fbd-bcf4-9c16d27c5eab

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 197/986 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC178 | c.2575A>G p.T859A (on ENST00000383096 / NM_001105528.3; = p.T821A on NM_198995.3) | Missense Mutation (SNP) | VAF 102/1190 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV55758809; called by muse, mutect2
- COL18A1 | c.2005G>A p.G669R (on ENST00000359759 / NM_130444.3; = p.G434R on NM_030582.4) | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766459944; called by muse, mutect2, varscan2
- KBTBD6 | c.1837dup p.C613Lfs*12 | Frame Shift Ins (INS) | VAF 148/690 reads (21%) | catalogued as rs1417700999; called by mutect2, varscan2
- KLC1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs189060211, COSV55807615; called by muse, mutect2, varscan2
- STAC3 | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 60/764 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV60413233; called by muse, mutect2
- CCDC168 | c.14708G>A p.R4903K | Missense Mutation (SNP) | VAF 32/672 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PEX11A | c.431T>A p.L144Q | Missense Mutation (SNP) | VAF 66/717 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.1); called by muse, mutect2
- TRMT2A | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.264); called by muse, mutect2
- CROT | c.237T>C p.N79= | Silent (SNP) | VAF 76/731 reads (10%) | catalogued as rs112310560; called by muse, mutect2, varscan2
- PLEKHG4B | c.531C>T p.P177= (on ENST00000283426; = p.P533= on NM_052909.5) | Silent (SNP) | VAF 26/363 reads (7%) | catalogued as rs756356701; called by muse, mutect2
- PLXND1 | c.3636G>A p.E1212= | Silent (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 41/1410 reads (3%) | called by muse, mutect2
- CUEDC1 | c.-76C>T | 5'UTR (SNP) | VAF 20/124 reads (16%) | catalogued as rs1205385412; called by muse, mutect2, varscan2
